Somatic mutation profile of tumor specimen TCGA-EE-A2MQ-06A (aliquot TCGA-EE-A2MQ-06A-11D-A197-08) from TCGA case TCGA-EE-A2MQ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.8 years (26,584 days).
Specimen TCGA-EE-A2MQ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3db5223e-7936-4e3e-b60c-05d4e496a3a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MQ-10A (Blood Derived Normal), aliquot TCGA-EE-A2MQ-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef4ce037-ca16-4fa9-83a8-b2800f19aaf1

The open-access MAF lists 310 somatic variants for this specimen: 202 protein-altering or splice-affecting, 101 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 179, Silent 101, Nonsense Mutation 14, Intron 5, Splice Site 5, Frame Shift Del 2, 5'UTR 1, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- HSD11B1 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 23/78 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54825651, COSV54826982; called by muse, mutect2, varscan2
- TP53 | c.375+2T>C p.X125_splice | Splice Site (SNP) | VAF 27/40 reads (68%) | hotspot (GDC flag); catalogued as rs1555526469, CS147127, COSV52663814, COSV52664353, COSV52730362; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55390237; called by muse, mutect2, varscan2
- ACBD3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1278923333, COSV64729525; called by mutect2, varscan2
- ADAMTS16 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV56976258; called by muse, mutect2, varscan2
- ADGRF5 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51929405, COSV51933191; called by muse, mutect2, varscan2
- ADGRV1 | c.6778C>T p.R2260* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs779821643, COSV67977499; called by muse, mutect2, varscan2
- AKR1C1 | c.280T>G p.L94V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV66498412; called by muse, mutect2
- AMER1 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs866313799, COSV57653761; called by mutect2, varscan2
- ANK1 | c.3856G>A p.E1286K | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV55871486; called by muse, mutect2, varscan2
- AP002512.3 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs201068692, COSV54405369, COSV54408841; called by muse, mutect2, varscan2
- APC | c.8348C>T p.P2783L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57320808; called by muse, mutect2, varscan2
- ARHGAP29 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV53107648; called by muse, mutect2, varscan2
- ATP2B3 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54839385; called by muse, mutect2, varscan2
- ATP8A1 | c.3092C>G p.A1031G | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52527448, COSV52531937; called by muse, mutect2, varscan2
- BEND2 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV66214937, COSV66217039; called by muse, mutect2, varscan2
- C19orf18 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.725); catalogued as COSV58704953; called by muse, mutect2, varscan2
- C9orf24 | c.708T>A p.C236* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV52623674; called by muse, mutect2, varscan2
- CACNA1A | c.4956G>C p.E1652D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV64188627; called by muse, mutect2
- CACNA2D3 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55510052; called by muse, mutect2, varscan2
- CACNG3 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs868272395, COSV50063799; called by muse, mutect2, varscan2
- CAPN6 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs766454026, COSV60693679; called by muse, mutect2, varscan2
- CASR | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.234); catalogued as rs121909262, CM950198, COSV56133823; called by muse, mutect2, varscan2
- CCDC88C | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs750472814, COSV66233488; called by muse, mutect2, varscan2
- CCNB3 | c.3314G>A p.G1105E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV52069417; called by muse, mutect2, varscan2
- CDHR1 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60559210; called by muse, mutect2, varscan2
- CEL | c.523A>G p.S175G (on ENST00000673714; = p.S172G on NM_001807.6) | Missense Mutation (SNP) | VAF 80/137 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60826122; called by muse, mutect2, varscan2
- CHD9 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV68296875; called by muse, mutect2, varscan2
- CHL1 | c.2716C>T p.P906S (on ENST00000397491 / NM_001253387.1; = p.P922S on NM_006614.4) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV56585283; called by muse, mutect2, varscan2
- CHRNB2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1336296723, COSV63807601, COSV63809376; called by mutect2, varscan2
- CIC | c.4121C>T p.P1374L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV50546542; called by muse, mutect2, varscan2
- COL14A1 | c.4204C>T p.R1402* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as rs776498858, COSV52846274; called by mutect2, varscan2
- COL4A4 | c.3076C>T p.P1026S | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.229); catalogued as rs1198659988, COSV61629250; called by muse, mutect2, varscan2
- COL8A1 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53728741; called by muse, mutect2, varscan2
- COL9A1 | c.2188G>A p.G730R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57877946; called by muse, mutect2, varscan2
- CPAMD8 | c.2941G>A p.G981R (on ENST00000651564; = p.G934R on NM_015692.5) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101488457; called by muse, mutect2
- CPPED1 | c.461G>C p.W154S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55495305; called by muse, mutect2, varscan2
- CPXM2 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV53855569; called by muse, mutect2, varscan2
- CR1 | c.5285G>A p.W1762* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100887491; called by muse, mutect2, varscan2
- CR1 | c.5286G>A p.W1762* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as rs1228805744, COSV100887492; called by muse, mutect2, varscan2
- CRB1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as rs868258281, COSV66328499; called by muse, mutect2, varscan2
- CSMD3 | c.1419C>T p.I473= (on ENST00000297405 / NM_001363185.1; = p.I369= on NM_052900.3) | Splice Region (SNP) | VAF 6/21 reads (29%) | catalogued as rs769731876, COSV52091242, COSV99851147; called by muse, mutect2, varscan2
- CUL5 | c.1310T>C p.V437A | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.855); catalogued as COSV63230010; called by muse, mutect2, varscan2
- CXorf38 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV59947213; called by muse, mutect2, varscan2
- CYLC2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs770475064, COSV66335876; called by muse, mutect2, varscan2
- DDIAS | c.2570A>G p.H857R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs753181127, COSV61271287; called by muse, varscan2
- DEUP1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV53209277; called by muse, mutect2, varscan2
- DPH1 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as COSV53983541; called by muse, mutect2, varscan2
- DPYSL5 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV56508538; called by muse, mutect2, varscan2
- EBF3 | c.1389T>A p.N463K (on ENST00000355311 / NM_001375392.1; = p.N454K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100799121; called by mutect2, varscan2
- EBF3 | c.1388A>C p.N463T (on ENST00000355311 / NM_001375392.1; = p.N454T on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV100799122; called by muse, mutect2, varscan2
- EBF3 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62471285; called by muse, mutect2, varscan2
- EEPD1 | c.989G>C p.R330P | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54195455; called by muse, mutect2, varscan2
- ESRP1 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 163/417 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64407452; called by muse, mutect2, varscan2
- EXOC3L1 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52044913; called by muse, varscan2
- FAM71F1 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59372696; called by muse, mutect2, varscan2
- FBXL13 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs777165290, COSV57534445; called by muse, mutect2, varscan2
- GCOM1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs369885749, COSV51087839; called by muse, varscan2
- GGA2 | c.1208C>T p.T403M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.132); catalogued as rs1281993791, COSV59167247; called by mutect2, varscan2
- GH2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60426144; called by muse, mutect2, varscan2
- GLRA3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771115012, COSV56857256; called by mutect2, varscan2
- GOLGB1 | c.2787G>C p.K929N | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV100511681, COSV61461317; called by muse, mutect2, varscan2
- GPD2 | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV60089756, COSV60093586; called by muse, mutect2
- GPRIN2 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs782034843, COSV65400095; called by muse, mutect2, varscan2
- HEPHL1 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1276684060, COSV59889178; called by muse, mutect2, varscan2
- HEPHL1 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765449710, COSV59889184; called by muse, mutect2, varscan2
- HYDIN | c.1130A>T p.H377L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV55475434; called by muse, mutect2, varscan2
- IGKV1D-16 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.115); catalogued as rs778494498; called by muse, mutect2, varscan2
- IL33 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV67343775; called by muse, mutect2, varscan2
- IL3RA | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 52/149 reads (35%) | catalogued as COSV58429644; called by muse, mutect2, varscan2
- ITPRID1 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV60069523; called by muse, mutect2, varscan2
- JPH3 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs753117984, COSV52463742; called by muse, mutect2, varscan2
- KCNJ3 | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54530638; called by muse, mutect2, varscan2
- KIAA1755 | c.3478C>T p.R1160W | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376293680; called by muse, mutect2, varscan2
- KITLG | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.075); catalogued as COSV57199815; called by muse, mutect2, varscan2
- KMT2D | c.14729C>T p.P4910L | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV99979425; called by muse, mutect2, varscan2
- KMT2D | c.14728C>T p.P4910S | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV99979428; called by muse, mutect2, varscan2
- KMT2D | c.6929C>T p.P2310L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs752346893, COSV56407410; called by muse, mutect2, varscan2
- KRT37 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1183641258, COSV56656687; called by muse, mutect2, varscan2
- KRTDAP | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.157); catalogued as COSV58864936; called by muse, mutect2, varscan2
- LAMA5 | c.5690C>T p.A1897V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV53351982; called by muse, varscan2
- LGALS9C | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV60194541; called by muse, mutect2, varscan2
- LPA | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV60295789; called by muse, mutect2, varscan2
- LUZP1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 99/173 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV56498103; called by muse, mutect2, varscan2
- MAN1A2 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62975931; called by muse, mutect2, varscan2
- MANBA | c.2488C>T p.P830S (on ENST00000642252; = p.P784S on NM_005908.4) | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); catalogued as COSV56962521; called by muse, mutect2, varscan2
- MCTP1 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145448158; called by muse, mutect2, varscan2
- ME1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63837315; called by muse, mutect2, varscan2
- MEP1A | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.376); catalogued as COSV57917704; called by muse, mutect2, varscan2
- MMUT | c.1427A>C p.Q476P | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51272217; called by muse, mutect2, varscan2
- MORC4 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55239082; called by muse, mutect2
- MTM1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV100080665, COSV60333518; called by muse, mutect2, varscan2
- MTUS2 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); catalogued as rs771233147, COSV70912331; called by mutect2, varscan2
- MUC16 | c.35000G>A p.G11667E | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.019); catalogued as rs764407502, COSV67441117; called by muse, mutect2, varscan2
- MUC16 | c.29641G>A p.E9881K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.909); catalogued as COSV67441127; called by muse, mutect2, varscan2
- MXRA5 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54222236; called by muse, mutect2, varscan2
- MYH4 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV55111317; called by mutect2, varscan2
- MYH7 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV62515821; called by muse, mutect2, varscan2
- MYO9B | c.2479A>G p.I827V | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.854); catalogued as rs1568290960, COSV68276654; called by muse, mutect2, varscan2
- N4BP3 | c.1442A>G p.E481G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs571513191, COSV51061651; called by muse, mutect2, varscan2
- NAP1L4 | c.534+1G>C p.X178_splice | Splice Site (SNP) | VAF 153/388 reads (39%) | catalogued as COSV65880480; called by muse, mutect2, varscan2
- NCOR1 | c.6640C>T p.R2214C | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs763924640, COSV51958968; called by muse, mutect2, varscan2
- NDOR1 | c.1390C>T p.P464S (on ENST00000371521 / NM_001144026.3; = p.P457S on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100788913; called by muse, mutect2
- NDOR1 | c.1391C>T p.P464L (on ENST00000371521 / NM_001144026.3; = p.P457L on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100789081, COSV61287368; called by muse, mutect2, varscan2
- NDST4 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as rs1190760162, COSV52107697; called by mutect2, varscan2
- NEB | c.14810G>A p.R4937Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs375307136, CM064144, COSV99414497; called by muse, mutect2, varscan2
- NLRP10 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as rs900658112, COSV60778448; called by muse, mutect2, varscan2
- NME8 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 80/141 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs186068152, COSV52246166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPY1R | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV56713152; called by muse, mutect2, varscan2
- NR2C1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as rs909537988, COSV58008481; called by muse, mutect2, varscan2
- NRG3 | c.2069C>A p.A690D (on ENST00000404547 / NM_001370084.1; = p.A666D on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64541966; called by muse, mutect2, varscan2
- NRK | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474166462, COSV54588750; called by mutect2, varscan2
- NRXN1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV67999826; called by muse, varscan2
- NXF3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV67702545; called by muse, mutect2, varscan2
- OR2A5 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV68738479; called by muse, mutect2, varscan2
- OR2T12 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV58775820; called by muse, mutect2, varscan2
- OR4E2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 77/102 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201192739, COSV57731367; called by muse, mutect2, varscan2
- OR51G1 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58968273; called by muse, mutect2, varscan2
- OR52A5 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56614050; called by muse, mutect2, varscan2
- OR52D1 | c.889G>T p.G297* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV59486877; called by muse, mutect2, varscan2
- OR6V1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs368094301; called by muse, mutect2, varscan2
- OTOF | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55494725; called by muse, mutect2, varscan2
- OVOL2 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs367914989, COSV53861555; called by mutect2, varscan2
- PADI4 | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.911); catalogued as COSV64922930; called by muse, mutect2
- PAH | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61013690; called by muse, mutect2, varscan2
- PALLD | c.3267G>T p.Q1089H (on ENST00000505667 / NM_001166108.2; = p.Q1072H on NM_016081.4) | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54971805; called by muse, mutect2, varscan2
- PCDHA10 | c.1551C>G p.Y517* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as COSV56474687; called by muse, varscan2
- PDZD4 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as COSV99381194; called by muse, mutect2, varscan2
- PDZD4 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV99381197; called by muse, mutect2, varscan2
- PHYH | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as rs1290322799, COSV53814526; called by muse, mutect2, varscan2
- PIKFYVE | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52236301; called by muse, mutect2, varscan2
- PITPNM1 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV56873092; called by muse, mutect2, varscan2
- PITX2 | c.278C>T p.T93I (on ENST00000354925 / NM_001204397.1; = p.T100I on NM_000325.6) | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60739987; called by muse, mutect2, varscan2
- PJVK | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV51845407, COSV51847440; called by muse, varscan2
- PLB1 | c.3480G>A p.W1160* | Nonsense Mutation (SNP) | VAF 37/105 reads (35%) | catalogued as COSV59818634; called by muse, mutect2, varscan2
- POM121L12 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV68692140; called by muse, mutect2, varscan2
- PPL | c.2771G>A p.R924K | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV52165372; called by muse, mutect2, varscan2
- PPP4R2 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 44/144 reads (31%) | catalogued as COSV55593843, COSV55596548; called by muse, mutect2, varscan2
- PRAG1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV58156940; called by muse, mutect2, varscan2
- PSORS1C2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs761407729, COSV52534948; called by muse, mutect2, varscan2
- PTPN23 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs1191059531, COSV55542357; called by muse, mutect2, varscan2
- PTPRT | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1423243089, COSV61957514, COSV61968538; called by muse, varscan2
- RAB3GAP2 | c.3239C>T p.P1080L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62781917; called by muse, mutect2, varscan2
- RAG1 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55023771; called by muse, mutect2, varscan2
- RBM10 | c.1667C>G p.T556S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV61307566; called by muse, mutect2
- RYR1 | c.14803G>A p.G4935S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM098042, COSV62087267; called by muse, mutect2, varscan2
- SCAF11 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1266831846, COSV65474569; called by muse, mutect2, varscan2
- SCN5A | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.014); catalogued as rs777042523, COSV60066863; called by muse, mutect2, varscan2
- SEMA5B | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV52089433; called by muse, mutect2, varscan2
- SGK1 | c.1129-1G>A p.X377_splice | Splice Site (SNP) | VAF 28/73 reads (38%) | catalogued as COSV99397989; called by muse, mutect2, varscan2
- SH3PXD2B | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV61124378; called by muse, mutect2, varscan2
- SHPRH | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV51604100; called by muse, mutect2, varscan2
- SIGLEC11 | c.1460G>A p.W487* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as COSV70221863; called by muse, mutect2, varscan2
- SLC16A13 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57273623; called by muse, mutect2, varscan2
- SLC25A42 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV59379260, COSV59381045; called by mutect2, varscan2
- SLC4A7 | c.3124C>T p.L1042F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55394446; called by muse, mutect2, varscan2
- SLC6A13 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356273077, COSV58255009; called by muse, varscan2
- SLCO6A1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs531357554, COSV65805246; called by muse, mutect2, varscan2
- SLF1 | c.3028C>T p.L1010F | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); catalogued as rs555585116, COSV54367180; called by muse, varscan2
- SPAM1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV56141005; called by muse, mutect2, varscan2
- SPEG | c.8470C>T p.P2824S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56662195; called by muse, mutect2, varscan2
- SPHKAP | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV60867408; called by muse, varscan2
- SPHKAP | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV60867421; called by muse, mutect2, varscan2
- STK24 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 171/223 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64822222; called by muse, mutect2, varscan2
- SYNE1 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54895846; called by muse, mutect2, varscan2
- TAS2R38 | c.829A>C p.I277L | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV71884914, COSV71885639; called by muse, mutect2, varscan2
- TENT4B | c.1703G>A p.R568K (on ENST00000561678 / NM_001365323.2; = p.R553K on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62546074; called by muse, mutect2, varscan2
- THOC2 | c.4247C>T p.P1416L | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV55539515; called by muse, mutect2, varscan2
- TM4SF4 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1293337765, COSV59514955; called by mutect2, varscan2
- TMC7 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV58581260; called by muse, mutect2, varscan2
- TMEM26 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as COSV53261031; called by muse, mutect2, varscan2
- TP73 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV60698030; called by muse, mutect2, varscan2
- TRHDE | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as rs200482271, COSV53857265; called by muse, mutect2, varscan2
- TRRAP | c.6670C>T p.P2224S (on ENST00000359863 / NM_001244580.1; = p.P2206S on NM_003496.3) | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV62837934; called by muse, mutect2, varscan2
- TTC27 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1000718914, COSV58648357; called by muse, mutect2, varscan2
- TTN | c.85336G>A p.E28446K (on ENST00000591111; = p.E21022K on NM_003319.4) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | PolyPhen benign (0.194); catalogued as COSV59863211; called by muse, mutect2, varscan2
- TTN | c.23690C>T p.S7897F (on ENST00000591111; = p.S6970F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | PolyPhen possibly damaging (0.821); catalogued as COSV59863262; called by muse, mutect2, varscan2
- TTN | c.15028G>A p.D5010N (on ENST00000591111; = p.D4083N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | PolyPhen probably damaging (0.998); catalogued as rs868056944, COSV100612811, COSV59863267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.4610G>A p.G1537D (on ENST00000591111; = p.G1491D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | PolyPhen probably damaging (1); catalogued as COSV59863273; called by muse, varscan2
- TYK2 | c.3227A>G p.Y1076C | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777199847, COSV53384325; called by muse, mutect2, varscan2
- TYRP1 | c.420A>C p.E140D | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV66357677; called by muse, mutect2, varscan2
- UGT3A2 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763384831, COSV56928089, COSV56933550; called by muse, mutect2, varscan2
- UROC1 | c.1243+1G>A p.X415_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99331152; called by muse, mutect2, varscan2
- UROC1 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773336510, COSV99331155; called by muse, mutect2, varscan2
- USH2A | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs368754739; called by muse, mutect2, varscan2
- USP34 | c.7471G>A p.E2491K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV68397450; called by muse, mutect2, varscan2
- VRTN | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 63/80 reads (79%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV56438972; called by muse, mutect2, varscan2
- WIPF2 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.352); catalogued as COSV60271945; called by muse, mutect2, varscan2
- ZDHHC17 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58350015; called by muse, mutect2, varscan2
- ZDHHC6 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 45/116 reads (39%) | catalogued as COSV61128611; called by muse, mutect2, varscan2
- ZMYM6 | c.475T>C p.S159P | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV58183434; called by muse, mutect2, varscan2
- ZNF142 | c.4566G>C p.E1522D (on ENST00000411696 / NM_001379660.1; = p.E1322D on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV68742844; called by muse, mutect2, varscan2
- ZNF331 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs770166196, COSV53474358; called by muse, mutect2, varscan2
- ZNF385D | c.250A>C p.I84L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV55744943; called by muse, mutect2, varscan2
- ZNF7 | c.1888A>G p.I630V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57382448; called by muse, mutect2, varscan2
- ZNF804A | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866013097, COSV56433687; called by muse, mutect2, varscan2
- BBS10 | c.821_822del p.E274Vfs*29 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- CTSE | c.585del p.S196Pfs*7 (on ENST00000360218; = p.S191Pfs*7 on NM_001910.4) | Frame Shift Del (DEL) | VAF 37/85 reads (44%) | called by mutect2, pindel, varscan2
- PAFAH1B3 | c.453_455del p.K151del | In Frame Del (DEL) | VAF 38/89 reads (43%) | called by pindel, varscan2
- TACR3 | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.107); called by muse, mutect2
- TRBV19 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACSM1 | c.1392C>T p.F464= | Silent (SNP) | VAF 107/249 reads (43%) | catalogued as rs1444829933, COSV54632741; called by muse, mutect2, varscan2
- ACSM4 | c.1440C>T p.Y480= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs757924910, COSV68066497; called by muse, mutect2, varscan2
- ADAMTS18 | c.2922C>T p.L974= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV51398260; called by muse, mutect2, varscan2
- ANK2 | c.11196G>A p.E3732= | Silent (SNP) | VAF 42/68 reads (62%) | catalogued as rs1425247026, COSV52143771; called by muse, mutect2, varscan2
- ANK3 | c.6018G>A p.A2006= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs778890531, COSV55042474; called by muse, varscan2
- ATOH1 | c.1017G>A p.G339= | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as COSV60037287; called by muse, mutect2, varscan2
- ATP7A | c.1023G>A p.G341= | Silent (SNP) | VAF 96/239 reads (40%) | catalogued as rs374656309, CD078717, COSV58441793; called by muse, mutect2, varscan2
- BCAT1 | c.957C>T p.A319= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV53906784; called by muse, mutect2, varscan2
- BMPER | c.1557G>A p.V519= | Silent (SNP) | VAF 64/115 reads (56%) | catalogued as rs868718269, COSV51810639; called by muse, mutect2, varscan2
- CACNG3 | c.942C>T p.P314= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs201263434, COSV50063834; called by muse, mutect2, varscan2
- CALB2 | c.282C>T p.T94= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs745602535, COSV56937813; called by muse, mutect2, varscan2
- CCDC141 | c.3117C>T p.S1039= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV55368090; called by muse, mutect2, varscan2
- CCDC185 | c.1401G>A p.R467= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs1460945830, COSV64820153; called by muse, mutect2, varscan2
- CEACAM7 | c.322C>T p.L108= | Silent (SNP) | VAF 70/318 reads (22%) | catalogued as rs1555811267, COSV99137176; called by muse, mutect2, varscan2
- CEACAM7 | c.321C>T p.T107= | Silent (SNP) | VAF 72/323 reads (22%) | catalogued as COSV99137177; called by muse, mutect2, varscan2
- CEP290 | c.5337C>T p.I1779= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1367796637, COSV58348095; called by mutect2, varscan2
- CFTR | c.1290C>T p.F430= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs764640445, COSV50040471; called by muse, mutect2, varscan2
- CHRNG | c.1260G>A p.P420= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs376569365; called by muse, mutect2, varscan2
- CILK1 | c.1248C>A p.S416= (on ENST00000350082 / NM_001375397.1; = p.S409= on NM_014920.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV63153239; called by muse, mutect2, varscan2
- CLCNKA | c.915C>T p.T305= | Silent (SNP) | VAF 61/108 reads (56%) | catalogued as COSV58890188; called by muse, mutect2, varscan2
- CLEC3B | c.87G>A p.K29= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV56109342; called by muse, mutect2, varscan2
- COL15A1 | c.1323C>T p.S441= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as rs769564877, COSV66640939; called by muse, mutect2, varscan2
- COL22A1 | c.948C>T p.I316= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as rs1316115519, COSV57321154; called by muse, mutect2, varscan2
- COL25A1 | c.378G>A p.G126= | Silent (SNP) | VAF 30/52 reads (58%) | catalogued as rs761109932, COSV101211292; called by muse, mutect2, varscan2
- COL6A3 | c.6402A>T p.G2134= | Silent (SNP) | VAF 194/466 reads (42%) | catalogued as COSV55078392; called by muse, varscan2
- CPAMD8 | c.1890C>T p.F630= (on ENST00000651564; = p.F583= on NM_015692.5) | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs776271256, COSV52230579; called by muse, mutect2, varscan2
- DDR2 | c.970C>T p.L324= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV63368960; called by muse, mutect2, varscan2
- DENND1C | c.192C>T p.P64= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs1293114727, COSV67371871; called by muse, varscan2
- DGAT2 | c.939C>T p.I313= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV57175163; called by muse, mutect2, varscan2
- DISP1 | c.3996C>T p.I1332= | Silent (SNP) | VAF 169/378 reads (45%) | catalogued as COSV52653987; called by muse, mutect2, varscan2
- DNAH5 | c.2829G>A p.R943= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV54201479, COSV54224868; called by muse, mutect2, varscan2
- DRAP1 | c.528C>T p.F176= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs1206185051, COSV56988007; called by muse, varscan2
- EPHA10 | c.306C>T p.F102= | Silent (SNP) | VAF 36/174 reads (21%) | catalogued as rs138523815; called by mutect2, varscan2
- EPHX4 | c.1038G>A p.V346= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs1384900947, COSV100952678, COSV64888898, COSV64890163; called by muse, mutect2, varscan2
- FBXO7 | c.921C>G p.L307= | Silent (SNP) | VAF 60/174 reads (34%) | catalogued as COSV56675525; called by muse, mutect2, varscan2
- FRA10AC1 | c.345C>T p.F115= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV63270738; called by muse, mutect2, varscan2
- FRMPD3 | c.2625C>T p.L875= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99345754, COSV99345998; called by muse, mutect2, varscan2
- GABPB2 | c.582C>T p.L194= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as rs374570194, COSV64460420; called by muse, mutect2, varscan2
- GABRA6 | c.714G>A p.R238= | Silent (SNP) | VAF 35/55 reads (64%) | catalogued as COSV50877396; called by muse, mutect2, varscan2
- GOLGA3 | c.2463C>T p.S821= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as rs202095140, COSV52624479; called by muse, varscan2
- GRHL2 | c.1092G>A p.E364= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV52543891, COSV99306264; called by muse, mutect2, varscan2
- HEPHL1 | c.3393G>A p.V1131= | Silent (SNP) | VAF 72/173 reads (42%) | catalogued as COSV59889193; called by muse, mutect2, varscan2
- HTR2B | c.1269G>A p.E423= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV51448854; called by muse, mutect2, varscan2
- IGSF3 | c.1233C>T p.I411= (on ENST00000369486 / NM_001007237.3; = p.I431= on NM_001542.4) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs964368662, COSV59584766; called by mutect2, varscan2
- IL17RD | c.480C>T p.F160= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs542398760, COSV56334702; called by muse, mutect2, varscan2
- INTS6L | c.1107T>C p.F369= | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as COSV66083496; called by muse, mutect2, varscan2
- ITGA11 | c.1113T>C p.F371= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV59874546; called by muse, mutect2, varscan2
- KATNAL2 | c.321G>A p.G107= (on ENST00000356157 / NM_001353899.1; = p.G35= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/157 reads (62%) | catalogued as COSV55292625; called by muse, mutect2, varscan2
- KCNJ3 | c.51A>G p.T17= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV54530630; called by muse, varscan2
- KIAA1755 | c.3477C>T p.F1159= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs1217108457, COSV99641770; called by muse, mutect2, varscan2
- KLHL38 | c.1347C>T p.I449= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV58085829; called by muse, mutect2, varscan2
- KLHL38 | c.597C>T p.A199= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV58085840; called by muse, mutect2, varscan2
- MAGEC1 | c.372C>T p.V124= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV53567262; called by muse, mutect2, varscan2
- MROH7 | c.48G>A p.K16= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV59867422; called by muse, mutect2, varscan2
- MXRA5 | c.2163G>A p.E721= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV54222256; called by muse, mutect2, varscan2
- MYMK | c.387C>T p.I129= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as rs749420718, COSV60599982; called by muse, mutect2, varscan2
- NFIX | c.1191G>A p.Q397= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV62175268; called by muse, mutect2, varscan2
- NLRP5 | c.1953C>T p.V651= | Silent (SNP) | VAF 30/38 reads (79%) | catalogued as COSV66761745; called by muse, mutect2, varscan2
- OIT3 | c.354G>A p.T118= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs765853644, COSV61824892; called by muse, mutect2, varscan2
- OR10S1 | c.243C>T p.F81= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV73342643, COSV73342740; called by muse, mutect2, varscan2
- OR2L2 | c.657G>A p.R219= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as COSV63547452, COSV63560389; called by muse, mutect2, varscan2
- OR2W3 | c.456G>A p.G152= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV64455939, COSV64457938; called by muse, mutect2, varscan2
- OR4B1 | c.336G>A p.L112= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as COSV58881796; called by muse, mutect2, varscan2
- OR8D1 | c.204C>T p.F68= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs142777403, COSV63441629; called by muse, mutect2, varscan2
- P2RX3 | c.1179C>T p.F393= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV54441302; called by muse, mutect2, varscan2
- PCDHGB2 | c.1992C>T p.F664= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as rs865898330, COSV53892254; called by mutect2, varscan2
- PCNX2 | c.4629G>A p.T1543= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs757432332, COSV50780709; called by mutect2, varscan2
- PCSK7 | c.336C>T p.A112= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV56117458; called by muse, mutect2, varscan2
- PHF3 | c.4021C>T p.L1341= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as COSV100013359, COSV50312875; called by muse, mutect2, varscan2
- PRKCB | c.1818G>A p.E606= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV57764014; called by muse, mutect2, varscan2
- RAG1 | c.2971C>T p.L991= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV55023779; called by muse, mutect2, varscan2
- REEP6 | c.180C>T p.L60= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV52012024, COSV52012783; called by muse, mutect2, varscan2
- RYR3 | c.9750C>T p.I3250= (on ENST00000389232; = p.I3251= on NM_001036.6) | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV66776218; called by muse, mutect2, varscan2
- S100A9 | c.237C>T p.F79= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV64199517; called by muse, mutect2, varscan2
- SEMA3A | c.501G>A p.G167= | Silent (SNP) | VAF 144/253 reads (57%) | catalogued as COSV54860366; called by muse, varscan2
- SEZ6L | c.387G>A p.R129= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV50657617; called by muse, mutect2, varscan2
- SFXN5 | c.837C>T p.L279= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV55584321; called by muse, mutect2, varscan2
- SLC16A14 | c.459C>T p.F153= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV54616502; called by muse, mutect2, varscan2
- SLC25A12 | c.1239T>G p.V413= | Silent (SNP) | VAF 46/142 reads (32%) | catalogued as COSV55531247; called by muse, mutect2, varscan2
- SLC39A7 | c.297G>A p.E99= | Silent (SNP) | VAF 70/108 reads (65%) | catalogued as COSV63399423; called by muse, mutect2, varscan2
- SLITRK3 | c.558C>T p.P186= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV53845253; called by muse, mutect2, varscan2
- SMARCD3 | c.69C>T p.V23= | Silent (SNP) | VAF 69/134 reads (51%) | catalogued as COSV51265623; called by muse, mutect2, varscan2
- SPEF2 | c.4545C>T p.T1515= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs1285493431, COSV57426673; called by muse, mutect2, varscan2
- SPG7 | c.1191C>T p.I397= (on ENST00000268704; = p.I404= on NM_003119.4) | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as rs765347604, COSV51947309; called by muse, mutect2, varscan2
- SSR1 | c.366C>T p.A122= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV55201874; called by muse, mutect2, varscan2
- STK40 | c.876C>T p.T292= | Silent (SNP) | VAF 30/44 reads (68%) | catalogued as COSV63734527; called by muse, mutect2, varscan2
- TCF7L2 | c.1563C>T p.P521= (on ENST00000355995 / NM_001367943.1; = p.P498= on NM_030756.5) | Silent (SNP) | VAF 111/299 reads (37%) | catalogued as COSV53335750; called by muse, mutect2, varscan2
- TET2 | c.2874G>A p.Q958= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV54395283; called by muse, mutect2, varscan2
- TINAGL1 | c.1161C>T p.S387= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV99592731; called by muse, varscan2
- TNNC1 | c.273G>A p.G91= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV51766682, COSV51768124; called by muse, mutect2, varscan2
- TRHDE | c.2121G>A p.R707= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99670020; called by muse, mutect2, varscan2
- TRRAP | c.9615T>C p.L3205= (on ENST00000359863 / NM_001244580.1; = p.L3176= on NM_003496.3) | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV62837944; called by muse, mutect2, varscan2
- TTN | c.49371C>T p.T16457= (on ENST00000591111; = p.T9033= on NM_003319.4) | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV59863243; called by muse, mutect2, varscan2
- UBQLNL | c.354G>A p.T118= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs368343827; called by muse, mutect2, varscan2
- VPS13C | c.8181C>T p.F2727= (on ENST00000644861 / NM_020821.3; = p.F2684= on NM_017684.5) | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV51119978; called by muse, mutect2, varscan2
- ZBTB16 | c.1473C>T p.F491= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV60088785; called by muse, mutect2, varscan2
- ZBTB37 | c.546G>A p.L182= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as COSV62931266; called by muse, mutect2, varscan2
- ZDHHC17 | c.435A>G p.K145= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV58350009; called by muse, mutect2, varscan2
- ZDHHC21 | c.534C>T p.A178= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as rs1469788047, COSV66611994; called by muse, mutect2, varscan2
- ZNF292 | c.7299A>T p.S2433= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV60535052; called by muse, mutect2, varscan2
- ZNF804A | c.183C>T p.L61= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100170575, COSV56433676; called by muse, varscan2
- DCAF13 | c.-11G>A | 5'UTR (SNP) | VAF 26/50 reads (52%) | catalogued as COSV52566515; called by muse, mutect2, varscan2
- HECTD4 | c.3442-20C>T | Intron (SNP) | VAF 37/91 reads (41%) | catalogued as COSV61177496; called by muse, mutect2, varscan2
- NACA | c.71-2305C>T | Intron (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100771200; called by muse, mutect2, varscan2
- PML | c.1710+1195C>T | Intron (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99166854; called by muse, mutect2, varscan2
- POLE | c.6658-313A>G | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-12874C>T | Intron (SNP) | VAF 54/89 reads (61%) | called by muse, mutect2, varscan2
- SNORD113-7 | n.53C>T | RNA (SNP) | VAF 95/122 reads (78%) | called by muse, mutect2, varscan2
